Somatic mutation profile of tumor specimen 0DI6KY from CCDI case PBBVCS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroendocrine carcinoma, NOS; Tissue or organ of origin: Appendix; Age at diagnosis: 16.5 years (6,023 days).
Specimen 0DI6KY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f6eedf2-6f9a-4851-9840-8beafb3207cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e94acc8f-95fb-44c1-9803-1832930775a6

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PRDM5 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 141/667 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs756946467, COSV53359645, COSV53359880, COSV53369535; called by muse, mutect2, varscan2
- TNFRSF10C | c.736G>A p.V246I | Missense Mutation (SNP) | VAF 206/814 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as rs143879407; called by muse, varscan2
- BCAM | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 104/575 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP9X | c.4604-2A>G p.X1535_splice | Splice Site (SNP) | VAF 69/185 reads (37%) | called by muse, mutect2, varscan2
- TPBG | c.528G>A p.V176= | Silent (SNP) | VAF 51/195 reads (26%) | called by muse, mutect2, varscan2
- TRIM51GP | c.1230A>G p.G410= | Silent (SNP) | VAF 74/390 reads (19%) | catalogued as rs934391382; called by muse, mutect2, varscan2
